Somatic mutation profile of tumor specimen TCGA-B7-5816-01A (aliquot TCGA-B7-5816-01A-21D-1600-08) from TCGA case TCGA-B7-5816, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 51.2 years (18,698 days).
Specimen TCGA-B7-5816-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2061f9b9-ac70-4f91-a8f1-5ed83fd7b334.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B7-5816-10A (Blood Derived Normal), aliquot TCGA-B7-5816-10A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98cdf592-17fd-40b0-96ad-85e6214e30d3

The open-access MAF lists 1,297 somatic variants for this specimen: 1,020 protein-altering or splice-affecting, 265 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 742, Silent 265, Frame Shift Del 186, Nonsense Mutation 32, Frame Shift Ins 28, Splice Site 19, In Frame Del 7, Intron 6, Splice Region 5, 5'Flank 2, 3'Flank 2, 3'UTR 1.

Variants (750 of 1,297; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.11083del p.S3695Afs*27 | Frame Shift Del (DEL) | VAF 12/106 reads (11%) | catalogued as rs1412574975, CM074695; ClinVar: uncertain significance / likely pathogenic; called by mutect2, pindel, varscan2
- C6 | c.2450A>C p.K817T | Missense Mutation (SNP) | VAF 43/265 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV54704910, COSV54705322; called by muse, mutect2, varscan2
- CAPN3 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs863224958, CM040389, COSV58819321; ClinVar: likely pathogenic; called by muse, mutect2
- COL2A1 | c.4316C>T p.T1439M | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as rs121912886, CM014699, COSV61527816; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.6081del p.P2029Lfs*177 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | catalogued as rs780623622, CD961934; ClinVar: pathogenic; called by pindel, varscan2
- DDX3X | c.741C>T p.G247= (on ENST00000399959; = p.G248= on NM_001356.5) | Silent (SNP) | VAF 20/184 reads (11%) | catalogued as rs1569238002, COSV67863076; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNAH5 | c.5563dup p.I1855Nfs*6 | Frame Shift Ins (INS) | VAF 20/160 reads (13%) | catalogued as rs752925056; ClinVar: pathogenic; called by mutect2, varscan2
- EPB42 | c.839G>A p.R280Q (on ENST00000441366 / NM_001114134.2; = p.R310Q on NM_000119.3) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121917734, CM950361, COSV55748513; ClinVar: pathogenic; called by muse, mutect2
- FAH | c.615del p.F205Lfs*2 | Frame Shift Del (DEL) | VAF 17/181 reads (9%) | catalogued as rs1057517084; ClinVar: likely pathogenic; called by mutect2, pindel
- KANSL1 | c.779del p.G260Vfs*19 | Frame Shift Del (DEL) | VAF 20/192 reads (10%) | catalogued as rs748018297; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 27/251 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs772110575, COSV55879949, COSV56003293; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 19/149 reads (13%) | catalogued as rs121913289; ClinVar: pathogenic; called by pindel, varscan2*
- PTPN11 | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 15/187 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121918457, CM021672, COSV61005439; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- RECQL | c.120del p.V41Sfs*2 | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | catalogued as rs745659712, COSV59084411; ClinVar: pathogenic; called by mutect2, varscan2
- SMARCA4 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 7/47 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238758086, COSV60785486, COSV60802491; ClinVar: other / uncertain significance; called by muse, mutect2, varscan2
- TCF4 | c.1829C>T p.A610V | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1568303352, CM091864, COSV61890423; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.2139G>A p.M713I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV59382890; called by muse, mutect2
- AAAS | c.1366del p.Q456Sfs*95 | Frame Shift Del (DEL) | VAF 13/119 reads (11%) | catalogued as rs767701527, CM030396; called by mutect2, pindel, varscan2
- ABAT | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755435740, COSV51620243; called by mutect2, varscan2
- ABCA1 | c.6035T>C p.L2012P | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV66063767; called by muse, mutect2
- ABCA13 | c.7772T>C p.L2591S | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71283381; called by muse, mutect2
- ABCA13 | c.11539G>A p.V3847M | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71283384; called by muse, mutect2
- ABCB1 | c.2153C>T p.A718V | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV55945151, COSV99713028; called by muse, mutect2, varscan2
- ABCC2 | c.4156C>A p.L1386M | Missense Mutation (SNP) | VAF 70/604 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1183312226, COSV64984565; called by muse, mutect2, varscan2
- ABCC3 | c.778T>C p.W260R | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53317223; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCC6 | c.4213G>T p.G1405C | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM080026, COSV52741250; called by muse, mutect2, varscan2
- ABCC8 | c.4606G>A p.A1536T | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.387); catalogued as rs772332005, COSV56846274; called by muse, mutect2, varscan2
- ABCC9 | c.2716C>A p.L906I | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53962631; called by muse, mutect2, varscan2
- ABCF1 | c.2246C>T p.A749V (on ENST00000326195 / NM_001025091.2; = p.A711V on NM_001090.3) | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777572931, COSV58227852; called by muse, mutect2
- ACTRT2 | c.911dup p.T305Hfs*9 | Frame Shift Ins (INS) | VAF 15/128 reads (12%) | catalogued as rs777174619; called by mutect2, pindel
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 110/228 reads (48%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM12 | c.1996G>T p.G666C | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64102516; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2393G>A p.R798Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.595); catalogued as rs373621869, COSV54996365; called by muse, varscan2
- ADAMTSL4 | c.2417G>A p.R806Q | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587625880, COSV54996393; called by muse, varscan2
- ADAMTSL4 | c.3135G>T p.Q1045H | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54996428; called by muse, mutect2, varscan2
- ADAT1 | c.1028G>T p.R343I | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57185252; called by muse, mutect2, varscan2
- ADCY6 | c.1374C>T p.I458= | Splice Region (SNP) | VAF 33/315 reads (10%) | catalogued as COSV57166218; called by muse, mutect2, varscan2
- ADCY7 | c.2159C>T p.P720L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs757281639, COSV54264440; called by muse, mutect2, varscan2
- ADGRD1 | c.1283A>G p.Y428C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55438925; called by muse, mutect2, varscan2
- ADGRE1 | c.2057A>G p.E686G | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51672026; called by muse, mutect2, varscan2
- ADGRE1 | c.2221C>T p.R741C | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs149410886; called by muse, mutect2, varscan2
- ADNP2 | c.971del p.P324Lfs*8 | Frame Shift Del (DEL) | VAF 14/114 reads (12%) | catalogued as rs772825390; called by mutect2, pindel, varscan2
- ADORA3 | c.691T>G p.S231A | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV53984968; called by muse, mutect2
- AFDN | c.257T>A p.L86Q | Missense Mutation (SNP) | VAF 104/489 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60037696; called by muse, mutect2, varscan2
- AGL | c.2591G>A p.R864Q | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.079); catalogued as rs776599112, CM140956, COSV54048187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGPAT5 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1362816409, COSV53445550; called by muse, mutect2, varscan2
- AHCYL1 | c.1198T>C p.S400P | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.799); catalogued as COSV63208203; called by muse, mutect2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 24/91 reads (26%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKR1B1 | c.871A>C p.S291R | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV53646427; called by muse, mutect2
- ALCAM | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 32/301 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV60245317; called by muse, mutect2, varscan2
- ALOXE3 | c.1436C>T p.T479M | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs372053788; called by muse, mutect2, varscan2
- ALPK1 | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs1288395844, COSV51581902; called by muse, mutect2, varscan2
- ALS2CL | c.2785T>G p.C929G | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59670104; called by muse, mutect2
- AMPD3 | c.361A>C p.T121P (on ENST00000396553 / NM_001025389.2; = p.T130P on NM_000480.3) | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV67329871; called by muse, mutect2, varscan2
- ANGEL1 | c.1864T>C p.Y622H | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV51871844; called by muse, mutect2, varscan2
- ANKEF1 | c.87G>T p.E29D | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65691945; called by muse, mutect2
- ANKRD11 | c.4172A>C p.Q1391P | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.007); catalogued as rs779013481, COSV56354803; called by muse, mutect2, varscan2
- ANKRD7 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54553897; called by muse, mutect2
- ANO9 | c.1708C>A p.L570I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.603); catalogued as COSV60382389, COSV60383166; called by muse, mutect2, varscan2
- AP1M2 | c.392T>C p.L131P | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs753387578, COSV51565509; called by mutect2, varscan2
- AP2B1 | c.467T>C p.V156A | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV51997014; called by muse, mutect2
- AP3B1 | c.1111T>C p.Y371H | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.147); catalogued as COSV54876443; called by muse, mutect2
- AP3D1 | c.1652A>C p.Q551P | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.845); catalogued as COSV61424520; called by muse, mutect2, varscan2
- APBB1IP | c.579G>T p.M193I | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV63076071; called by muse, mutect2, varscan2
- APOBEC3H | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV62378495; called by muse, mutect2, varscan2
- AQR | c.805T>G p.W269G | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as COSV50029600; called by muse, mutect2
- ARFGAP3 | c.855A>C p.Q285H | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs537612856, COSV54310498; called by muse, mutect2
- ARHGEF10 | c.1580C>A p.A527E (on ENST00000398564; = p.A502E on NM_014629.4) | Missense Mutation (SNP) | VAF 28/257 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.901); catalogued as COSV50642540; called by muse, varscan2
- ARHGEF2 | c.1411C>T p.R471C (on ENST00000361247 / NM_001162383.2; = p.R443C on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58106417; called by muse, mutect2, varscan2
- ARHGEF5 | c.677A>C p.E226A | Missense Mutation (SNP) | VAF 24/420 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs761818562; called by muse, mutect2
- ARID1A | c.2060C>A p.P687H | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV61371863; called by muse, mutect2
- ARL14EP | c.266del p.N89Ifs*4 | Frame Shift Del (DEL) | VAF 22/200 reads (11%) | catalogued as rs1247324796; called by mutect2, varscan2
- ARMC12 | c.383C>A p.T128N (on ENST00000373866 / NM_001286574.2; = p.T155N on NM_145028.5) | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as rs766322738, COSV99849336; called by muse, mutect2, varscan2
- ARSI | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60816658; called by muse, mutect2, varscan2
- ASCC3 | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 16/118 reads (14%) | catalogued as rs747570359; called by mutect2, varscan2
- ASL | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs775839623, COSV59187908; called by muse, mutect2, varscan2
- ATAD2 | c.2435C>A p.A812D | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54877345; called by muse, mutect2, varscan2
- ATAD3C | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs752441562, COSV58019223; called by mutect2, varscan2
- ATF4 | c.406del p.Q136Rfs*3 | Frame Shift Del (DEL) | VAF 40/341 reads (12%) | catalogued as rs770192882; called by mutect2, varscan2
- ATG2A | c.5663del p.G1888Afs*2 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | catalogued as COSV100815511; called by mutect2, pindel, varscan2
- ATMIN | c.1928C>T p.S643L | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs762686054, COSV55145125; called by muse, mutect2, varscan2
- ATP10A | c.3938A>C p.K1313T | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.045); catalogued as COSV63513539; called by muse, mutect2, varscan2
- ATP1A3 | c.257C>T p.P86L (on ENST00000545399 / NM_001256214.2; = p.P73L on NM_152296.5) | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1161880070, COSV57485078; called by muse, mutect2
- ATP1B3 | c.345A>G p.K115= | Splice Region (SNP) | VAF 16/159 reads (10%) | catalogued as COSV53948898; called by muse, mutect2, varscan2
- ATP2C1 | c.2387G>A p.R796H | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.124); catalogued as rs1286861425, COSV60752585; called by muse, mutect2, varscan2
- ATP6AP1 | c.1294A>G p.T432A | Missense Mutation (SNP) | VAF 50/475 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV63895228; called by muse, mutect2
- ATP6V0A1 | c.2234G>T p.S745I (on ENST00000343619 / NM_001378531.1; = p.S739I on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52870692; called by muse, mutect2, varscan2
- AURKA | c.251T>A p.V84E | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.139); catalogued as COSV57167331; called by muse, mutect2, varscan2
- BAAT | c.1029G>T p.Q343H | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV52287180, COSV52290644; called by muse, mutect2
- BAHD1 | c.1069A>C p.M357L | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs775425103, COSV69083602; called by muse, mutect2, varscan2
- BAP1 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56236367; called by muse, mutect2
- BBS9 | c.2571A>C p.E857D (on ENST00000242067 / NM_001348036.1; = p.E817D on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV54156705; called by muse, mutect2, varscan2
- BCL7C | c.617dup p.L207Tfs*10 | Frame Shift Ins (INS) | VAF 16/156 reads (10%) | catalogued as rs754078059; called by mutect2, varscan2
- BCOR | c.5071A>G p.T1691A (on ENST00000378444 / NM_001123385.2; = p.T1657A on NM_017745.6) | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs1409439985, COSV60699762; called by muse, mutect2, varscan2
- BHMT2 | c.209T>C p.V70A | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV54871841; called by muse, mutect2
- BORCS5 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1565944436, COSV53801038; called by muse, mutect2, varscan2
- BRD1 | c.748T>C p.Y250H | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as COSV53454775; called by muse, mutect2, varscan2
- BRD4 | c.3566C>T p.A1189V | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as rs368540009; called by muse, mutect2, varscan2
- BRWD1 | c.424A>T p.N142Y | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.675); catalogued as COSV58122296; called by muse, mutect2
- BTBD11 | c.1682C>T p.A561V (on ENST00000280758 / NM_001018072.2; = p.A98V on NM_001017523.2) | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1368588123, COSV55016681; called by muse, mutect2, varscan2
- C10orf88 | c.1338A>C p.*446Yext*42 | Nonstop Mutation (SNP) | VAF 16/108 reads (15%) | catalogued as COSV64403592; called by muse, mutect2
- C1QTNF3 | c.84+5G>A | Splice Region (SNP) | VAF 31/331 reads (9%) | catalogued as COSV99180682; called by muse, mutect2
- C1S | c.986A>G p.E329G | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as COSV61070039; called by muse, mutect2
- C1orf53 | c.301T>C p.Y101H | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV66323284; called by muse, mutect2
- C3 | c.2678C>T p.S893L | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs745503980, COSV55568636; called by muse, mutect2, varscan2
- C3orf20 | c.2367del p.K790Sfs*9 | Frame Shift Del (DEL) | VAF 13/121 reads (11%) | catalogued as rs762124133; called by mutect2, pindel, varscan2
- CA11 | c.593T>A p.L198H | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99320499; called by muse, mutect2
- CABIN1 | c.2092C>G p.R698G | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54077586; called by muse, mutect2, varscan2
- CACNA1E | c.1170A>C p.A390= | Splice Region (SNP) | VAF 7/52 reads (13%) | catalogued as COSV62382249, COSV62435070; called by mutect2, varscan2
- CACNA1E | c.3773G>A p.R1258Q | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62382257; called by muse, mutect2
- CACNA1G | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1335556091, COSV61720237; called by muse, mutect2, varscan2
- CALN1 | c.149G>A p.R50Q (on ENST00000329008 / NM_001017440.3; = p.R92Q on NM_031468.4) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as rs753498969, COSV61118039, COSV61119958; called by muse, mutect2, varscan2
- CAPN13 | c.1699T>C p.W567R | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV99699763; called by muse, mutect2, varscan2
- CAPN9 | c.1388del p.P463Lfs*6 | Frame Shift Del (DEL) | VAF 28/276 reads (10%) | catalogued as rs778837710; called by mutect2, pindel, varscan2
- CCDC110 | c.587A>G p.N196S | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV56869378; called by muse, mutect2, varscan2
- CCDC170 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV53336632; called by muse, mutect2, varscan2
- CCDC180 | c.4683A>C p.K1561N | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV63826828; called by muse, mutect2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC39 | c.1979A>G p.Q660R | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs1352168921, COSV56478669; called by muse, mutect2
- CCDC40 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs749446675, CD110046, COSV53896615; called by mutect2, varscan2
- CCDC69 | c.95A>G p.H32R | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1393255005, COSV62599082; called by muse, mutect2
- CCDC88A | c.2335del p.I779Sfs*4 | Frame Shift Del (DEL) | VAF 22/180 reads (12%) | catalogued as COSV55059558; called by mutect2, pindel, varscan2
- CCT6B | c.1078T>C p.F360L | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.279); catalogued as COSV58487832; called by muse, mutect2, varscan2
- CD164 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 9/89 reads (10%) | catalogued as COSV51532827; called by muse, mutect2, varscan2
- CDH11 | c.2332C>A p.R778S | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV51751364, COSV51762463; called by muse, mutect2
- CDHR1 | c.2050C>T p.R684W | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.857); catalogued as rs1448332690, COSV60559540; called by muse, mutect2
- CDHR2 | c.2746A>G p.I916V | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); catalogued as COSV56134667; called by muse, mutect2
- CDK12 | c.3350C>A p.A1117E | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV70999282, COSV71000594; called by muse, mutect2
- CDK16 | c.1162G>T p.G388C | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52090958; called by muse, mutect2
- CDK2 | c.371T>C p.L124P | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57185938, COSV57187726; called by muse, mutect2, varscan2
- CDR1 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 54/230 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV65163842; called by muse, mutect2, varscan2
- CEBPZ | c.1428del p.D477Mfs*11 | Frame Shift Del (DEL) | VAF 17/144 reads (12%) | catalogued as rs763090473; called by mutect2, varscan2
- CELF4 | c.277A>G p.M93V | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.05); catalogued as rs1178655253, COSV58446460; called by muse, mutect2
- CELSR1 | c.3383C>A p.P1128Q | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs370921649; called by muse, mutect2, varscan2
- CELSR3 | c.5802del p.S1935Afs*4 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | catalogued as rs1205203585, COSV50840268; called by mutect2, pindel, varscan2
- CEMIP | c.3455C>A p.A1152D | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV54988139; called by muse, mutect2
- CEP128 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as COSV53672496; called by muse, mutect2, varscan2
- CERS5 | c.940A>G p.N314D | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV58188354; called by muse, mutect2
- CFH | c.2899G>A p.G967R | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66405801, COSV66412245; called by muse, mutect2, varscan2
- CFHR5 | c.1339G>T p.A447S | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV56818029; called by muse, mutect2, varscan2
- CHD1L | c.1432A>T p.I478L | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV63612721; called by muse, mutect2, varscan2
- CHGB | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as COSV66759583, COSV66760171; called by muse, mutect2, varscan2
- CHL1 | c.1238A>G p.N413S (on ENST00000397491 / NM_001253387.1; = p.N429S on NM_006614.4) | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.718); catalogued as COSV56586542; called by muse, mutect2, varscan2
- CHST12 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0.015); catalogued as rs1477486505, COSV51673754; called by muse, mutect2
- CKLF-CMTM1 | c.108dup p.I37Yfs*7 | Frame Shift Ins (INS) | VAF 34/387 reads (9%) | catalogued as rs1443302361; called by mutect2, pindel
- CLCA4 | c.2138A>G p.N713S | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65282220; called by muse, mutect2, varscan2
- CLCN4 | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV66465167; called by muse, mutect2, varscan2
- CLDN4 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs868948159, COSV52894907; called by muse, mutect2, varscan2
- CLEC16A | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 42/343 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68497894; called by muse, mutect2, varscan2
- CLOCK | c.2340G>T p.Q780H | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV100011597; called by muse, mutect2, varscan2
- CNGA4 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 29/234 reads (12%) | SIFT tolerated (0.91); PolyPhen benign (0.005); catalogued as rs774738730, COSV66005048; called by muse, mutect2, varscan2
- CNOT6 | c.750del p.L251Wfs*2 | Frame Shift Del (DEL) | VAF 38/254 reads (15%) | catalogued as COSV56160927; called by mutect2, pindel, varscan2
- CNTNAP5 | c.2702C>T p.S901L | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs756576914, COSV70472877; called by muse, mutect2
- COL10A1 | c.130A>G p.I44V | Missense Mutation (SNP) | VAF 41/482 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.088); catalogued as COSV54572110; called by muse, mutect2
- COL6A1 | c.2618T>C p.V873A | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV62611508; called by muse, mutect2, varscan2
- COL6A3 | c.2993C>T p.S998L | Missense Mutation (SNP) | VAF 41/375 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as rs774161895, COSV55079700; called by muse, mutect2, varscan2
- COQ8B | c.1414G>A p.V472M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs772770880, COSV53284257; called by muse, mutect2, varscan2
- CORO2A | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.318); catalogued as COSV59661944; called by muse, mutect2, varscan2
- CPEB1 | c.1483G>A p.G495S (on ENST00000617958; = p.G430S on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55617209; called by muse, mutect2
- CPEB2 | c.2381C>A p.P794H | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.07); catalogued as COSV52589313; called by muse, mutect2, varscan2
- CPT1B | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.646); catalogued as rs750222036, COSV100376485; called by mutect2, varscan2
- CPT1B | c.80C>G p.A27G | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as COSV56415064; called by muse, mutect2, varscan2
- CR1L | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 90/377 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54322574; called by muse, mutect2, varscan2
- CR2 | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs750302661, COSV65506041; called by muse, mutect2, varscan2
- CRAT | c.495del p.K166Sfs*5 | Frame Shift Del (DEL) | VAF 31/309 reads (10%) | catalogued as rs772054700, COSV58879005; called by mutect2, pindel
- CREBBP | c.6253C>T p.Q2085* | Nonsense Mutation (SNP) | VAF 39/212 reads (18%) | catalogued as COSV52114252; called by muse, mutect2, varscan2
- CRELD1 | c.841T>C p.C281R | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1293760021, COSV55976340; called by muse, mutect2, varscan2
- CRNKL1 | c.2374G>A p.D792N | Missense Mutation (SNP) | VAF 28/522 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV58548060; called by muse, mutect2
- CRYBA1 | c.569_571del p.G190del | In Frame Del (DEL) | VAF 31/220 reads (14%) | catalogued as rs770296091; called by pindel, varscan2
- CRYGB | c.514A>G p.M172V | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV53679684; called by muse, mutect2, varscan2
- CSH2 | c.509G>A p.S170N | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs764750547, COSV61080011; called by muse, mutect2, varscan2
- CSK | c.386A>G p.Y129C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54972542; called by muse, mutect2, varscan2
- CSNK1E | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as rs1209553878, COSV63290375; called by muse, mutect2
- CSPG5 | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1246833442, COSV53129907; called by muse, mutect2, varscan2
- CST8 | c.332C>A p.S111Y | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV55670502, COSV55672064; called by muse, mutect2
- CST9L | c.211G>T p.G71W | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as COSV65407527; called by muse, mutect2, varscan2
- CSTF1 | c.1222A>G p.T408A | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as COSV53857846; called by muse, mutect2
- CSTF3 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1459100494, COSV60609457; called by muse, mutect2
- CTIF | c.1118A>G p.D373G | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV56479563; called by muse, mutect2
- CTNNB1 | c.1379T>C p.I460T | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV62689729; called by muse, mutect2, varscan2
- CUEDC1 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as rs1196085417, COSV64226021; called by muse, mutect2, varscan2
- CUL1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs1297726612, COSV57386362; called by muse, mutect2
- CUL4A | c.1858+2T>C p.X620_splice (on ENST00000375440 / NM_001008895.4; = p.X520_splice on NM_003589.3) | Splice Site (SNP) | VAF 17/154 reads (11%) | catalogued as COSV58371184; called by muse, mutect2, varscan2
- CX3CL1 | c.512dup p.T172Dfs*41 | Frame Shift Ins (INS) | VAF 8/69 reads (12%) | catalogued as rs1408713344; called by mutect2, pindel, varscan2
- CYP26A1 | c.487A>G p.S163G | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.034); catalogued as COSV99814569; called by muse, mutect2
- DAP3 | c.217del p.Q73Rfs*16 | Frame Shift Del (DEL) | VAF 14/154 reads (9%) | catalogued as rs757230517; called by mutect2, pindel, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | catalogued as COSV99245498; called by mutect2, pindel, varscan2
- DAZAP2 | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.857); catalogued as COSV66312815; called by muse, mutect2
- DBNDD1 | c.34A>G p.I12V (on ENST00000002501 / NM_001042610.3; = p.I32V on NM_024043.3) | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.029); catalogued as COSV50021821, COSV50021892; called by muse, mutect2, varscan2
- DCAF1 | c.2701C>T p.R901* | Nonsense Mutation (SNP) | VAF 16/125 reads (13%) | catalogued as COSV60040549, COSV60044106; called by muse, mutect2, varscan2
- DCAF12L1 | c.760C>A p.P254T | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV64423102; called by muse, mutect2
- DCHS1 | c.5044G>A p.G1682R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55030520; called by muse, mutect2
- DDI1 | c.830A>C p.N277T | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV56368585; called by muse, mutect2
- DDX49 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV53229445; called by muse, mutect2, varscan2
- DENND2B | c.440C>A p.P147H | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.219); catalogued as COSV100567143; called by muse, mutect2, varscan2
- DHCR24 | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.906); catalogued as rs780280056, COSV64874194; called by mutect2, varscan2
- DKK2 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.634); catalogued as COSV53393642; called by muse, mutect2, varscan2
- DLAT | c.1397A>C p.K466T | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV54769041; called by muse, mutect2, varscan2
- DLG3 | c.1925A>G p.D642G (on ENST00000374360 / NM_021120.4; = p.D337G on NM_020730.3) | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV52079890; called by muse, mutect2, varscan2
- DNAH9 | c.4168A>G p.M1390V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV52334154; called by muse, mutect2, varscan2
- DNAH9 | c.12422_12424del p.E4141del | In Frame Del (DEL) | VAF 18/145 reads (12%) | catalogued as rs776735123; called by mutect2, pindel, varscan2
- DNAJC10 | c.1573A>G p.T525A | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51135786; called by muse, mutect2, varscan2
- DNAJC28 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 44/464 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.139); catalogued as COSV58721212; called by muse, mutect2
- DRC7 | c.1931G>A p.G644D | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.187); catalogued as COSV61052957; called by muse, mutect2
- DTX1 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as COSV57495641; called by muse, mutect2, varscan2
- DUXA | c.408A>C p.K136N | Missense Mutation (SNP) | VAF 45/404 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV73729492; called by muse, mutect2, varscan2
- DYNC1LI2 | c.942G>T p.W314C | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50754058, COSV50754749; called by muse, mutect2
- DYNC2H1 | c.6853C>T p.Q2285* | Nonsense Mutation (SNP) | VAF 11/102 reads (11%) | catalogued as rs1243279126, COSV62086209; called by muse, mutect2
- DYRK1A | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100117423; called by muse, varscan2
- DYRK3 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 8/162 reads (5%) | catalogued as rs1473119194, COSV100895676, COSV65605261; called by muse, mutect2
- DYSF | c.4585C>T p.R1529W | Missense Mutation (SNP) | VAF 64/554 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs375698433, CM080219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DZIP3 | c.2125G>C p.V709L | Missense Mutation (SNP) | VAF 19/226 reads (8%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV64311152; called by muse, mutect2
- E2F8 | c.1284G>T p.Q428H | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as COSV51461727, COSV51462894; called by muse, mutect2, varscan2
- E2F8 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.841); catalogued as rs1240222124, COSV51461815; called by muse, mutect2, varscan2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 13/91 reads (14%) | catalogued as rs369293935; called by mutect2, varscan2*
- ECT2 | c.2188A>C p.I730L (on ENST00000392692 / NM_001349098.2; = p.I699L on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV51686426; called by muse, mutect2
- EDN1 | c.124A>G p.S42G | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV65080410; called by muse, mutect2, varscan2
- EFEMP1 | c.188A>G p.N63S | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62615000; called by muse, mutect2
- EFEMP1 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62615013; called by muse, mutect2, varscan2
- EGR2 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1564706128, COSV54346185, COSV99654131; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EIF2AK3 | c.2909C>T p.T970M | Missense Mutation (SNP) | VAF 21/240 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs751166753, COSV57544965; called by muse, mutect2
- EIF3L | c.1385G>A p.S462N | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as COSV67739348; called by muse, mutect2, varscan2
- EIF3M | c.616A>G p.R206G | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV60072314; called by muse, mutect2
- EIF3M | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs780289523, COSV60072318; called by muse, mutect2, varscan2
- EME1 | c.254G>A p.S85N | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV56811650; called by muse, mutect2
- EML4 | c.737A>G p.N246S | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0.099); catalogued as COSV59293770; called by muse, mutect2
- ENAM | c.1191T>A p.N397K | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV68535200; called by muse, mutect2, varscan2
- EP400 | c.2360C>A p.A787D | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57762723; called by muse, mutect2, varscan2
- EPB41L2 | c.1772A>G p.D591G | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); catalogued as rs765506413, COSV61353114; called by muse, mutect2
- EPHA10 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57621331; called by muse, mutect2, varscan2
- EPHB1 | c.911G>T p.R304L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); catalogued as COSV67654085; called by muse, mutect2, varscan2
- EPS8 | c.2312C>T p.A771V | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.109); catalogued as rs772084003, COSV55527598; called by muse, mutect2, varscan2
- ERBB4 | c.1202T>C p.F401S | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV53502055; called by muse, mutect2, varscan2
- ERCC4 | c.2017+2T>C p.X673_splice | Splice Site (SNP) | VAF 5/51 reads (10%) | catalogued as COSV61310683; called by muse, mutect2
- ERN2 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 40/305 reads (13%) | catalogued as rs144370049; called by muse, mutect2, varscan2
- ESPL1 | c.2299C>T p.R767W | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1367056405, COSV57757341; called by muse, mutect2, varscan2
- ESPL1 | c.3850A>G p.T1284A | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs1178995191, COSV57757347; called by muse, mutect2
- EVI5 | c.19A>G p.T7A | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV64825518; called by muse, mutect2, varscan2
- EWSR1 | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs772636858, COSV100132071, COSV58421516; called by muse, mutect2
- EXO1 | c.2358del p.L787Yfs*37 (on ENST00000348581 / NM_001319224.1; = p.L787Yfs*60 on NM_003686.4) | Frame Shift Del (DEL) | VAF 11/107 reads (10%) | catalogued as rs1558148774, COSV62216239; called by mutect2, pindel, varscan2
- EXT2 | c.1679C>T p.P560L (on ENST00000343631; = p.P593L on NM_000401.3) | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59146836; called by muse, mutect2, varscan2
- FAM135B | c.2559G>T p.K853N | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV52705228; called by muse, mutect2, varscan2
- FAM135B | c.620T>G p.L207R | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52705256; called by muse, mutect2, varscan2
- FAM160B2 | c.1444G>A p.V482M | Missense Mutation (SNP) | VAF 22/231 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as rs574708720, COSV57156975; called by muse, mutect2
- FAM222B | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs375228705, COSV57927873; called by muse, mutect2
- FAM47B | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs368902203, COSV61452510, COSV61454357; called by muse, mutect2, varscan2
- FANCA | c.1625A>C p.E542A | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV66880176; called by muse, mutect2, varscan2
- FANCB | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.497); catalogued as rs757202355, COSV60758828; called by muse, mutect2
- FANCD2 | c.4370A>G p.Y1457C | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs920115796, COSV55032817; called by muse, mutect2
- FAT2 | c.9103G>A p.A3035T | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55813202; called by muse, mutect2
- FAT4 | c.10421C>T p.T3474I | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV58671603, COSV58683305; called by muse, mutect2, varscan2
- FBH1 | c.1498C>T p.R500C (on ENST00000362091 / NM_178150.3; = p.R551C on NM_032807.4) | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as rs748299182, COSV62981563; called by muse, mutect2, varscan2
- FBXO7 | c.891A>G p.I297M | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs146429630; called by muse, mutect2
- FBXW12 | c.1054G>T p.G352* | Nonsense Mutation (SNP) | VAF 25/190 reads (13%) | catalogued as COSV56482814; called by muse, mutect2, varscan2
- FCGR2A | c.253C>T p.H85Y (on ENST00000271450 / NM_001136219.3; = p.H84Y on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV54837084; called by muse, mutect2, varscan2
- FCRL3 | c.1060G>T p.G354W | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63839450; called by muse, mutect2, varscan2
- FGD5 | c.1079A>T p.E360V | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV53237295; called by muse, mutect2, varscan2
- FGD5 | c.4165G>T p.G1389C | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1217993628, COSV99547258; called by muse, mutect2
- FGF11 | c.443G>A p.C148Y | Missense Mutation (SNP) | VAF 70/361 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV53438961; called by muse, mutect2, varscan2
- FGF12 | c.182C>A p.P61Q | Missense Mutation (SNP) | VAF 18/345 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs1175722482, COSV53152374, COSV53155258, COSV53158085; called by muse, mutect2
- FGF13 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 36/406 reads (9%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.493); catalogued as COSV59542915; called by muse, mutect2
- FIGNL1 | c.926del p.K309Sfs*16 | Frame Shift Del (DEL) | VAF 15/144 reads (10%) | catalogued as rs1216734611; called by mutect2, pindel
- FILIP1 | c.2744C>T p.T915I | Missense Mutation (SNP) | VAF 32/303 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs554789463, COSV52722930; called by muse, mutect2, varscan2
- FN3KRP | c.794G>A p.G265D | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs866335413, COSV53928840; called by muse, mutect2
- FNIP2 | c.2529G>T p.K843N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as COSV52436538; called by muse, mutect2, varscan2
- FOXA3 | c.162del p.L55Sfs*84 | Frame Shift Del (DEL) | VAF 9/86 reads (10%) | catalogued as COSV100141144; called by mutect2, pindel, varscan2
- FOXN3 | c.737T>G p.L246R | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.949); catalogued as COSV99725770; called by muse, mutect2, varscan2
- FOXRED2 | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53398859; called by muse, mutect2, varscan2
- FRMPD2 | c.1610G>T p.R537M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV59715148; called by muse, mutect2, varscan2
- FSIP2 | c.19402G>A p.D6468N | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.106); catalogued as COSV100554024, COSV58091906; called by muse, mutect2
- FUNDC2 | c.379T>C p.Y127H | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65670394; called by muse, mutect2
- FUT11 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59539808; called by muse, mutect2, varscan2
- FZD10 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57472137; called by muse, mutect2, varscan2
- FZD6 | c.2066A>G p.H689R | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV62470589; called by muse, mutect2
- GABRA4 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs763817157, COSV51922640, COSV51927656; called by muse, mutect2, varscan2
- GABRE | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs752130096, COSV64818875; called by muse, mutect2, varscan2
- GALNT5 | c.2072G>A p.G691D | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52035793; called by muse, mutect2, varscan2
- GANAB | c.253-1G>T p.X85_splice | Splice Site (SNP) | VAF 8/88 reads (9%) | catalogued as COSV60461789; called by muse, mutect2
- GBP2 | c.1034C>T p.T345M | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs763248739, COSV65068468; called by muse, mutect2, varscan2
- GCC2 | c.1010T>C p.L337S | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59173991; called by muse, mutect2, varscan2
- GCG | c.230G>T p.W77L | Missense Mutation (SNP) | VAF 45/420 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1263899443, COSV64960825; called by muse, mutect2, varscan2
- GCM1 | c.965G>A p.S322N | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV52520815; called by muse, mutect2
- GDF5 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as rs1251554346, COSV65499231; called by mutect2, varscan2
- GDPD2 | c.757A>G p.T253A | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV65531947; called by muse, mutect2, varscan2
- GLT8D1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.116); catalogued as rs751467911, COSV56476568; called by muse, mutect2, varscan2
- GLUD2 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV60151333; called by muse, mutect2
- GOLGA2 | c.1175G>T p.S392I | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as COSV68596891; called by muse, mutect2, varscan2
- GOLIM4 | c.1860+2T>C p.X620_splice | Splice Site (SNP) | VAF 10/255 reads (4%) | catalogued as COSV58327889; called by muse, mutect2
- GON4L | c.394A>G p.K132E | Missense Mutation (SNP) | VAF 65/251 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs770667974, COSV55186633, COSV55187366; called by muse, mutect2, varscan2
- GP5 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as rs779182714, COSV55461458; called by muse, mutect2, varscan2
- GP6 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs781194651, COSV59976357; called by muse, mutect2, varscan2
- GRIN2A | c.1255G>A p.V419M | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58020274; called by muse, mutect2, varscan2
- GRM8 | c.2158del p.H720Tfs*12 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | catalogued as COSV58842099; called by mutect2, pindel, varscan2
- GRM8 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as rs757802889, COSV58801816, COSV58816405; called by muse, mutect2, varscan2
- GRPR | c.1147T>C p.Y383H | Missense Mutation (SNP) | VAF 38/404 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.188); catalogued as COSV66668924; called by muse, mutect2
- GSTA2 | c.587A>C p.K196T | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV72414571; called by muse, mutect2, varscan2
- GTF3C1 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 31/226 reads (14%) | catalogued as COSV62238875; called by muse, mutect2, varscan2
- GUCY2F | c.2927C>T p.P976L | Missense Mutation (SNP) | VAF 74/356 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs201541871, COSV54298433; called by muse, mutect2, varscan2
- GXYLT1 | c.796G>T p.G266* | Nonsense Mutation (SNP) | VAF 25/122 reads (20%) | catalogued as COSV55132475; called by muse, mutect2, varscan2
- H2BC10 | c.19T>C p.S7P | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV59952592; called by muse, mutect2
- HCN2 | c.1343T>C p.M448T | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV52112416; called by muse, mutect2, varscan2
- HCN3 | c.751A>G p.I251V | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as rs1244924132, COSV64233275; called by muse, mutect2, varscan2
- HDAC10 | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs541010302, COSV50536545; called by muse, mutect2, varscan2
- HDLBP | c.3110G>A p.R1037H | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs1559478259, COSV60492020; called by muse, mutect2, varscan2
- HECW2 | c.4331G>T p.R1444I | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53649548; called by muse, mutect2, varscan2
- HHAT | c.653C>A p.P218H | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54791406; called by muse, mutect2, varscan2
- HIF1A | c.2384T>C p.L795P | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60188174; called by muse, mutect2
- HIVEP3 | c.5138G>T p.G1713V | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as COSV56009690; called by muse, mutect2, varscan2
- HMX3 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as rs750180442, COSV63501529; called by muse, mutect2
- HNRNPDL | c.1202G>A p.S401N | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.932); catalogued as rs767472810, COSV55022149; called by muse, mutect2, varscan2
- HOXA11 | c.895del p.I299Lfs*30 | Frame Shift Del (DEL) | VAF 28/176 reads (16%) | catalogued as rs777829525; called by mutect2, varscan2
- HR | c.1052del p.G351Vfs*12 | Frame Shift Del (DEL) | VAF 22/155 reads (14%) | catalogued as rs750438737; called by mutect2, pindel
- HRG | c.1381C>T p.L461F | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51644006; called by muse, mutect2
- HSD17B12 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 38/298 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV53496811; called by muse, varscan2
- HSDL1 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.826); catalogued as rs761002851, COSV54740244; called by muse, mutect2, varscan2
- HSPA1A | c.1867G>T p.G623W | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); catalogued as COSV65148638; called by muse, mutect2, varscan2
- HTATIP2 | c.371G>A p.C124Y | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1383688291, COSV70040973; called by muse, mutect2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | catalogued as rs748579647; called by mutect2, pindel, varscan2
- HUWE1 | c.2517A>C p.K839N | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as rs1048630107, COSV53334702; called by muse, mutect2, varscan2
- HYDIN | c.7221G>T p.R2407S | Missense Mutation (SNP) | VAF 22/235 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.23); catalogued as rs899953650; called by muse, mutect2
- IFI16 | c.252del p.E85Kfs*3 | Frame Shift Del (DEL) | VAF 10/115 reads (9%) | catalogued as rs1557862995; called by mutect2, pindel
- IFNA16 | c.379G>T p.V127F | Missense Mutation (SNP) | VAF 95/408 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as rs372545467, COSV66509767; called by muse, mutect2, varscan2
- IKZF2 | c.1387G>T p.G463* | Nonsense Mutation (SNP) | VAF 23/365 reads (6%) | catalogued as COSV59576522; called by muse, mutect2
- IKZF2 | c.125G>A p.S42N | Missense Mutation (SNP) | VAF 28/458 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as COSV59576529; called by muse, mutect2
- INF2 | c.1864del p.R622Gfs*18 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | catalogued as rs1459726028; called by mutect2, pindel, varscan2
- INO80C | c.224A>G p.E75G | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs373752255, COSV52033870; called by muse, mutect2, varscan2
- INPP4A | c.2845C>T p.R949C (on ENST00000074304 / NM_001134224.1; = p.R910C on NM_004027.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1476692844, COSV50785306; called by muse, mutect2, varscan2
- INPP5F | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); catalogued as COSV62819647; called by muse, mutect2, varscan2
- INPPL1 | c.1497+2T>C p.X499_splice | Splice Site (SNP) | VAF 13/192 reads (7%) | catalogued as COSV53353211; called by muse, mutect2
- INPPL1 | c.1967_1969del p.S656del | In Frame Del (DEL) | VAF 6/55 reads (11%) | catalogued as rs746559845; called by mutect2, pindel, varscan2
- INSR | c.1610+1G>A p.X537_splice | Splice Site (SNP) | VAF 7/62 reads (11%) | catalogued as COSV57157583; called by muse, mutect2, varscan2
- INVS | c.374G>T p.R125M | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV52438061; called by muse, mutect2
- IP6K2 | c.913G>T p.G305C | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV53659654; called by muse, mutect2, varscan2
- IPO11 | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1251947599, COSV100320384, COSV57571987; called by muse, mutect2, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 25/195 reads (13%) | catalogued as rs1561359523; called by mutect2, varscan2
- IQCE | c.581G>A p.G194D | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as COSV58076484; called by muse, mutect2, varscan2
- IQCF2 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368553100; called by muse, mutect2, varscan2
- IQGAP3 | c.1570+2T>C p.X524_splice | Splice Site (SNP) | VAF 21/142 reads (15%) | catalogued as COSV63249361; called by muse, mutect2, varscan2
- IRAK4 | c.1181A>C p.Q394P | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as COSV71210277; called by muse, varscan2
- IRF2 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66928504; called by muse, mutect2, varscan2
- ISLR2 | c.2017C>T p.Q673* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV62301635; called by muse, mutect2, varscan2
- ISM2 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as rs755026075, COSV53633889; called by muse, mutect2
- ITGA2 | c.2201C>T p.A734V | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs148414859; called by muse, mutect2, varscan2
- ITGB1BP2 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52135721; called by muse, mutect2, varscan2
- ITGB8 | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as rs768194871, COSV56004933; called by muse, mutect2, varscan2
- JADE2 | c.1984G>A p.G662R | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs150023113; called by muse, mutect2
- JAZF1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as rs1204368248, COSV52232680; called by muse, mutect2
- JMJD7-PLA2G4B | c.1043A>G p.Q348R | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.215); catalogued as rs766090750, COSV100583667; called by muse, mutect2, varscan2
- KANK3 | c.2276T>C p.L759P | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV56846004; called by muse, mutect2, varscan2
- KCNA1 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1053557642, COSV66836572; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 15/129 reads (12%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNE4 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755849909, COSV56054017; called by muse, mutect2, varscan2
- KCNH1 | c.857T>G p.L286R | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as COSV55069756, COSV55079390, COSV99661871; called by muse, mutect2, varscan2
- KCNJ10 | c.968A>G p.Y323C | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63632827; called by muse, mutect2, varscan2
- KCNJ6 | c.933G>A p.M311I | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.993); catalogued as COSV55709493; called by muse, mutect2, varscan2
- KCNK7 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs78054727, COSV58418287, COSV58420149; called by muse, mutect2, varscan2
- KCNK9 | c.730C>A p.L244I | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV57278111; called by muse, mutect2, varscan2
- KCTD16 | c.1149del p.A384Lfs*20 | Frame Shift Del (DEL) | VAF 14/116 reads (12%) | catalogued as rs753765917, COSV72577101; called by mutect2, varscan2
- KDELR3 | c.584_586del p.F195del | In Frame Del (DEL) | VAF 25/179 reads (14%) | catalogued as rs756771962; called by pindel, varscan2
- KDM5A | c.3597del p.G1200Dfs*9 | Frame Shift Del (DEL) | VAF 24/186 reads (13%) | catalogued as rs771545848; called by mutect2, varscan2
- KIAA1109 | c.4770del p.K1590Nfs*11 | Frame Shift Del (DEL) | VAF 14/117 reads (12%) | catalogued as rs779140281, COSV52689741; called by mutect2, varscan2
- KIAA1109 | c.6278T>C p.V2093A | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV52662371; called by muse, mutect2
- KIAA1522 | c.862del p.Q288Rfs*8 (on ENST00000373480 / NM_001198972.2; = p.Q347Rfs*8 on NM_020888.3) | Frame Shift Del (DEL) | VAF 9/87 reads (10%) | catalogued as COSV53867890; called by mutect2, pindel, varscan2
- KIF12 | c.1063A>G p.T355A (on ENST00000640217; = p.T217A on NM_138424.1) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV65116631; called by muse, mutect2
- KIF14 | c.2798T>C p.M933T | Missense Mutation (SNP) | VAF 30/261 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs568570558, COSV66259849; called by muse, mutect2, varscan2
- KIF21B | c.2395C>T p.R799* | Nonsense Mutation (SNP) | VAF 5/50 reads (10%) | catalogued as rs1248086878; called by muse, mutect2
- KIF2B | c.1510C>T p.R504W | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757000396, COSV52127134; called by mutect2, varscan2
- KIF4B | c.362T>G p.L121R | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as COSV70527821; called by muse, mutect2, varscan2
- KIF5B | c.2552G>A p.R851H | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs200746362, COSV56650812; called by muse, mutect2, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 36/358 reads (10%) | catalogued as COSV54711577; called by mutect2, pindel
- KLHDC3 | c.802C>A p.L268I | Missense Mutation (SNP) | VAF 26/348 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as COSV55063529; called by muse, mutect2
- KLHL25 | c.1287del p.L430Cfs*11 | Frame Shift Del (DEL) | VAF 15/92 reads (16%) | catalogued as rs1459896064; called by mutect2, pindel, varscan2
- KLRG2 | c.67G>T p.G23* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV61800350; called by muse, mutect2
- KNTC1 | c.6215C>T p.P2072L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs370269719, COSV100338564; called by muse, mutect2, varscan2
- KPRP | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.027); catalogued as rs1454934158, COSV64220960; called by muse, mutect2, varscan2
- KRI1 | c.1706A>G p.D569G | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV57263554; called by muse, mutect2
- KRR1 | c.1142del p.K381Sfs*8 | Frame Shift Del (DEL) | VAF 21/122 reads (17%) | catalogued as rs761148574; called by mutect2, varscan2
- KRT16 | c.665G>A p.G222D | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV56966974; called by muse, mutect2
- KRT7 | c.1081C>A p.L361M | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV57765520, COSV57766469; called by muse, mutect2
- KRT72 | c.1519A>C p.K507Q | Missense Mutation (SNP) | VAF 48/351 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.082); catalogued as COSV53373221, COSV53376181; called by muse, mutect2, varscan2
- KRTAP13-3 | c.306del p.F102Lfs*9 | Frame Shift Del (DEL) | VAF 11/56 reads (20%) | catalogued as COSV61880665; called by mutect2, pindel, varscan2
- LAMA1 | c.6089C>T p.A2030V | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs761631965, COSV67531116; called by muse, mutect2, varscan2
- LAMA4 | c.1499G>T p.R500M (on ENST00000230538 / NM_001105206.3; = p.R493M on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV57892015, COSV57896603; called by muse, mutect2
- LAMB3 | c.2072G>A p.G691D | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs777788000, COSV61915283; called by muse, mutect2, varscan2
- LAMB4 | c.3762A>C p.Q1254H | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV52713313; called by muse, mutect2, varscan2
- LAMC1 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 52/407 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51132524, COSV99278997; called by muse, mutect2, varscan2
- LARS2 | c.1139G>A p.S380N | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV55525224; called by muse, mutect2
- LCMT2 | c.2056C>T p.Q686* | Nonsense Mutation (SNP) | VAF 19/202 reads (9%) | catalogued as rs1256551294, COSV59789481; called by muse, mutect2, varscan2
- LDLRAD3 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 21/288 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as rs746974845, COSV100214275; called by muse, mutect2
- LGI3 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60442899; called by muse, mutect2, varscan2
- LIAS | c.107del p.K36Rfs*31 | Frame Shift Del (DEL) | VAF 51/287 reads (18%) | catalogued as rs748571616; called by mutect2, varscan2
- LIG3 | c.2096A>G p.Y699C | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs765806516, COSV52005784; called by muse, mutect2, varscan2
- LILRA1 | c.385G>C p.A129P | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52177854; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 14/120 reads (12%) | catalogued as rs780042765; called by mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 24/180 reads (13%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMNB1 | c.1349A>G p.D450G | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV54396646; called by muse, mutect2
- LRAT | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs1231354939, COSV100312134, COSV60476467; called by muse, mutect2, varscan2
- LRIF1 | c.415G>T p.G139C | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.948); catalogued as COSV63896639; called by muse, mutect2
- LRIT3 | c.823T>C p.C275R | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59983090; called by muse, mutect2, varscan2
- LRP1B | c.12436G>A p.G4146S | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV67186650; called by muse, varscan2
- LRP1B | c.7657C>T p.R2553* | Nonsense Mutation (SNP) | VAF 22/80 reads (28%) | catalogued as rs140801406, COSV67186652; called by muse, mutect2, varscan2
- LRP1B | c.7079C>T p.T2360I | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as COSV67186654, COSV67208002; called by muse, mutect2, varscan2
- LRP1B | c.5644A>G p.M1882V | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV67186660; called by muse, mutect2
- LRP5 | c.3391G>A p.A1131T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as rs1272835374, COSV53711452, COSV99591420; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP5 | c.3656G>A p.R1219H | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.454); catalogued as rs143924910, CM131539; called by muse, mutect2, varscan2
- LRRC43 | c.1471G>A p.V491M | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs372715448; called by muse, mutect2, varscan2
- LRRC43 | c.1680del p.I561Sfs*10 | Frame Shift Del (DEL) | VAF 9/67 reads (13%) | catalogued as rs748039371; called by mutect2, pindel, varscan2
- LRRC4B | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.427); catalogued as rs759714186, COSV65349204; called by muse, mutect2
- LRRC59 | c.260T>A p.L87H | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56813699; called by muse, mutect2
- LRRC8B | c.343C>A p.H115N | Missense Mutation (SNP) | VAF 30/343 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.481); catalogued as COSV58373056; called by muse, mutect2
- LRRIQ1 | c.678+2T>C p.X226_splice | Splice Site (SNP) | VAF 8/82 reads (10%) | catalogued as rs753288563, COSV67812633; called by mutect2, varscan2
- LSS | c.1702C>T p.R568W | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs769430360, COSV100710825, COSV62699964; called by muse, mutect2, varscan2
- LTB4R2 | c.1150G>A p.G384S (on ENST00000528054; = p.G353S on NM_019839.5) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs756992579, COSV51864542; called by muse, mutect2
- MACF1 | c.8057T>C p.L2686P | Missense Mutation (SNP) | VAF 15/85 reads (18%) | catalogued as rs1156380699, COSV57105828; called by muse, mutect2, varscan2
- MACF1 | c.18803del p.N6268Mfs*32 (on ENST00000372915; = p.N4313Mfs*32 on NM_012090.5) | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | catalogued as rs748961150; called by mutect2, pindel, varscan2
- MAG | c.361C>A p.L121M | Missense Mutation (SNP) | VAF 53/270 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV62698971; called by muse, mutect2, varscan2
- MAGEC1 | c.3164A>G p.E1055G | Missense Mutation (SNP) | VAF 57/273 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs762692975, COSV53567963; called by muse, mutect2, varscan2
- MAGEC3 | c.20G>T p.W7L | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as COSV100024963, COSV53576172; called by muse, varscan2
- MAGEE1 | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs782396748, COSV100819342, COSV63908872; called by muse, mutect2
- MAGT1 | c.409C>T p.P137S (on ENST00000618282 / NM_001367916.1; = p.P169S on NM_032121.5) | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63780888; called by muse, mutect2, varscan2
- MAN2B2 | c.2007-1G>T p.X669_splice | Splice Site (SNP) | VAF 8/150 reads (5%) | catalogued as COSV53450590; called by muse, mutect2
- MAN2B2 | c.2551G>A p.G851R | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.015); catalogued as rs778596906, COSV53450598; called by muse, mutect2, varscan2
- MAN2C1 | c.2866G>A p.V956I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.228); catalogued as rs201870425; called by muse, mutect2, varscan2
- MAP3K6 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54640479; called by muse, mutect2, varscan2
- MAP6 | c.1846G>A p.G616S | Missense Mutation (SNP) | VAF 38/300 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV59074162; called by muse, mutect2, varscan2
- MAP6 | c.1340A>G p.D447G | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV59074173; called by muse, mutect2
- MAPKAPK5 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.051); catalogued as rs745405567, COSV72431626; called by muse, mutect2
- MARK4 | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs146014354; called by muse, mutect2, varscan2
- MC5R | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 43/359 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1485593304, COSV61253907; called by muse, mutect2, varscan2
- MCC | c.601G>T p.G201* | Nonsense Mutation (SNP) | VAF 12/174 reads (7%) | catalogued as rs1315034857, COSV68724505; called by muse, mutect2
- MCF2L2 | c.2465C>T p.A822V | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV61049204, COSV61050152; called by muse, mutect2
- MCMDC2 | c.212A>G p.E71G | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV58033667; called by muse, mutect2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 32/264 reads (12%) | catalogued as rs750092100; called by mutect2, varscan2
- ME2 | c.1628A>G p.Y543C | Missense Mutation (SNP) | VAF 46/353 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV58422191; called by muse, mutect2, varscan2
- MED1 | c.1394T>C p.V465A | Missense Mutation (SNP) | VAF 58/445 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.294); catalogued as COSV56122344; called by muse, mutect2, varscan2
- MED12L | c.4699A>G p.T1567A | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV56368536; called by muse, mutect2
- METTL21A | c.236T>C p.V79A | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as rs1412348073, COSV55881143; called by muse, mutect2
- MGRN1 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV52148270; called by muse, mutect2
- MIEF1 | c.904T>C p.Y302H | Missense Mutation (SNP) | VAF 6/153 reads (4%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV57477582; called by muse, mutect2
- MLC1 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.079); catalogued as COSV61115956; called by muse, mutect2
- MLLT3 | c.1579G>A p.V527M | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1380847578, COSV63494843; called by muse, mutect2, varscan2
- MMP9 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs768427160, COSV63433743; called by muse, mutect2
- MON2 | c.83G>A p.C28Y | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV54802984; called by muse, mutect2
- MPO | c.1639C>T p.L547F | Missense Mutation (SNP) | VAF 73/308 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV51856855; called by muse, mutect2, varscan2
- MPO | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs761949874, COSV56561209; called by muse, mutect2, varscan2
- MRGPRE | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.124); catalogued as COSV67745498; called by muse, mutect2, varscan2
- MRGPRX1 | c.686G>C p.G229A | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV57105906, COSV57107930; called by muse, mutect2
- MRPL51 | c.97G>T p.G33C | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as COSV57519416; called by muse, mutect2
- MSH4 | c.572A>G p.N191S | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.017); catalogued as COSV54196604; called by muse, mutect2
- MSMO1 | c.349T>C p.Y117H | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.365); catalogued as COSV54969597; called by muse, mutect2, varscan2
- MST1R | c.2182C>T p.R728W | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs201008581; called by muse, mutect2, varscan2
- MTA1 | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV58755630; called by muse, mutect2, varscan2
- MTHFR | c.1799A>C p.E600A | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV57171350; called by muse, mutect2
- MTMR10 | c.1511T>C p.L504P | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV58727178; called by muse, mutect2, varscan2
- MTOR | c.2296del p.R766Dfs*11 | Frame Shift Del (DEL) | VAF 22/207 reads (11%) | catalogued as rs746242022, COSV63872312; called by mutect2, pindel, varscan2
- MUC16 | c.31195A>G p.T10399A | Missense Mutation (SNP) | VAF 50/378 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.206); catalogued as COSV67444877; called by muse, mutect2, varscan2
- MUC16 | c.24184G>A p.G8062R | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.919); catalogued as COSV67444886; called by muse, mutect2, varscan2
- MUC17 | c.3973A>G p.T1325A | Missense Mutation (SNP) | VAF 43/427 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV60280089; called by muse, mutect2, varscan2
- MYH14 | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs373197435; called by muse, mutect2
- MYH6 | c.5506G>A p.A1836T | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs769228763, COSV59304793; called by muse, mutect2
- MYO5C | c.3551A>G p.Q1184R | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.792); catalogued as COSV55902549; called by muse, mutect2, varscan2
- MYRF | c.789del p.S264Afs*8 (on ENST00000278836 / NM_001127392.3; = p.S255Afs*8 on NM_013279.4) | Frame Shift Del (DEL) | VAF 20/152 reads (13%) | catalogued as rs769274302, COSV53895135; called by mutect2, varscan2
- NAA16 | c.1548del p.F516Lfs*3 | Frame Shift Del (DEL) | VAF 21/129 reads (16%) | catalogued as rs749241638; called by mutect2, pindel, varscan2
- NAA80 | c.700A>G p.R234G (on ENST00000417393 / NM_001200018.2; = p.R256G on NM_012191.4) | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV56496734; called by muse, mutect2, varscan2
- NALCN | c.3829G>A p.D1277N | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs956285320, COSV51917977, COSV51946855; called by muse, mutect2, varscan2
- NCKAP1 | c.2143C>T p.R715C | Missense Mutation (SNP) | VAF 15/237 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV62939734; called by muse, mutect2
- NDN | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1217310499, COSV59358436; called by muse, mutect2, varscan2
- NDST2 | c.1729C>T p.R577* | Nonsense Mutation (SNP) | VAF 7/72 reads (10%) | catalogued as rs754863971, COSV55212759; called by mutect2, varscan2
- NEFH | c.2450del p.K817Rfs*4 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | catalogued as rs1569198114; called by mutect2, pindel, varscan2
- NEFL | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.168); catalogued as COSV55336237; called by muse, mutect2, varscan2
- NEIL2 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV52706174; called by muse, mutect2, varscan2
- NEK10 | c.2011G>A p.V671I | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1233913000, COSV58279860; called by muse, mutect2
- NELL1 | c.743C>A p.A248D | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54239258; called by muse, mutect2
- NEURL4 | c.3799del p.V1267* | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | catalogued as rs1202163680; called by mutect2, pindel, varscan2
- NHLRC3 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV61486138; called by muse, mutect2
- NKTR | c.2306C>T p.S769L | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as COSV51769331; called by muse, mutect2, varscan2
- NLGN1 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 50/348 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs202165284, COSV64323731; called by muse, mutect2, varscan2
- NLGN3 | c.386T>A p.I129N | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.361); catalogued as COSV62441696; called by muse, mutect2, varscan2
- NOL9 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.594); catalogued as rs201104106, COSV100891534, COSV66625287; called by muse, mutect2
- NOTCH1 | c.2443T>C p.C815R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1176627299, COSV53028477; called by muse, mutect2
- NPFFR2 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100441339, COSV58146335; called by muse, mutect2, varscan2
- NPR3 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54084390; called by muse, mutect2, varscan2
- NR2F1 | c.701C>G p.A234G | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV59067504, COSV59068293; called by muse, mutect2
- NRCAM | c.2166G>T p.M722I (on ENST00000379028 / NM_001371124.1; = p.M706I on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61031220; called by muse, mutect2, varscan2
- NRDC | c.150G>A p.M50I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.38); catalogued as rs1186067610, COSV100703696, COSV61401602; called by muse, mutect2
- NRIP1 | c.518A>C p.K173T | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.799); catalogued as COSV59655031; called by muse, mutect2
- NRROS | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100145351; called by muse, mutect2
- NSD3 | c.3928C>T p.R1310* | Nonsense Mutation (SNP) | VAF 16/155 reads (10%) | catalogued as COSV104395134, COSV57666971; called by muse, mutect2, varscan2
- NUP210 | c.2309T>A p.L770Q | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.77); catalogued as COSV99595572; called by muse, mutect2
- NUP214 | c.4292C>T p.S1431F | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as rs756348885, COSV63907593; called by muse, mutect2, varscan2
- NYNRIN | c.3898C>T p.P1300S | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.755); catalogued as COSV66841141; called by muse, mutect2
- ODC1 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as rs371443385; called by muse, mutect2, varscan2
- OLFML2B | c.1961C>T p.A654V | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs1321923590, COSV54193881; called by muse, mutect2, varscan2
- OR10S1 | c.630G>T p.E210D | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV73342656; called by muse, mutect2, varscan2
- OR13C8 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV58610452; called by muse, mutect2, varscan2
- OR2D3 | c.110T>C p.L37S | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV58572435; called by muse, mutect2, varscan2
- OR2G3 | c.506G>A p.C169Y | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60680790; called by muse, mutect2, varscan2
- OR4A15 | c.392T>C p.L131S | Missense Mutation (SNP) | VAF 62/479 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.558); catalogued as COSV59033640; called by muse, mutect2, varscan2
- OR4P4 | c.315del p.F105Lfs*4 | Frame Shift Del (DEL) | VAF 30/262 reads (11%) | catalogued as rs748398423; called by mutect2, pindel, varscan2
- OR4P4 | c.917T>C p.L306P | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.346); catalogued as COSV58920611; called by muse, mutect2
- OR51F1 | c.506T>G p.L169R | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as COSV100598875, COSV58578784; called by muse, mutect2, varscan2
- OR51M1 | c.191A>C p.N64T | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV60783790; called by muse, mutect2
- OR52N5 | c.921A>C p.K307N | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV57698419; called by muse, varscan2
- OR52N5 | c.795C>A p.F265L | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.075); catalogued as COSV57698425; called by muse, varscan2
- OR5D13 | c.901A>G p.N301D | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV62332701; called by muse, mutect2, varscan2
- OR5H1 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 50/589 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV100641622, COSV100641641; called by muse, mutect2, varscan2
- ORC5 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as rs369009943; called by muse, mutect2, varscan2
- OS9 | c.1978G>A p.G660R | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57726781, COSV57730293; called by muse, mutect2, varscan2
- OSBPL10 | c.1907T>C p.V636A | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as COSV67336266; called by muse, mutect2
- OSGIN2 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs141987995, COSV52407088; called by muse, mutect2
- OSR1 | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs907421037, COSV55344648; called by muse, mutect2, varscan2
- OTOL1 | c.1171del p.S391Pfs*6 | Frame Shift Del (DEL) | VAF 7/65 reads (11%) | catalogued as COSV100019816; called by mutect2, pindel
- OTOP2 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs532804031, COSV58880613, COSV58881462; called by muse, mutect2
- P2RY1 | c.914C>G p.T305R | Missense Mutation (SNP) | VAF 15/280 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59308842; called by muse, mutect2
- P4HA2 | c.1015G>A p.V339I | Missense Mutation (SNP) | VAF 31/468 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.089); catalogued as rs148040234; called by muse, mutect2
- P4HTM | c.1496G>A p.R499H (on ENST00000383729 / NM_177939.3; = p.R560H on NM_177938.2) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV59086053; called by muse, mutect2
- PAPPA | c.460del p.V154Sfs*21 | Frame Shift Del (DEL) | VAF 10/98 reads (10%) | catalogued as COSV100075668; called by mutect2, varscan2
- PARD3 | c.582+2T>C p.X194_splice | Splice Site (SNP) | VAF 12/132 reads (9%) | catalogued as COSV60745215, COSV60748459; called by muse, mutect2
- PARP14 | c.4469A>G p.H1490R | Missense Mutation (SNP) | VAF 37/355 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs919963682, COSV71734102; called by muse, mutect2, varscan2
- PAX2 | c.1105G>A p.G369S (on ENST00000428433 / NM_003987.5; = p.G346S on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as rs1215529286, COSV62290105; called by muse, mutect2
- PCDH1 | c.896T>A p.V299D | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54610923; called by muse, mutect2, varscan2
- PCDH11X | c.1777A>G p.T593A | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53442905; called by muse, mutect2, varscan2
- PCDH11X | c.1880C>G p.P627R | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV53442942; called by muse, mutect2, varscan2
- PCDH19 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55257726; called by muse, mutect2, varscan2
- PCDH9 | c.2464G>A p.G822S | Missense Mutation (SNP) | VAF 38/332 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60528931, COSV60530371; called by muse, mutect2, varscan2
- PCDH9 | c.652T>C p.Y218H | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1327124782, COSV60528939; called by muse, mutect2, varscan2
- PCDHA1 | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 19/267 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV100974243, COSV65372656; called by muse, mutect2
- PCDHA11 | c.1540G>A p.G514S | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56475229; called by muse, mutect2
- PCDHAC1 | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 9/113 reads (8%) | catalogued as rs782446148, COSV53836650; called by muse, mutect2
- PCDHB12 | c.276G>C p.R92S | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV53393087; called by muse, mutect2
- PCDHB2 | c.326A>C p.Q109P | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV52029235, COSV52037890; called by muse, mutect2
- PCDHB3 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV50564161; called by muse, mutect2, varscan2
- PCDHB3 | c.2323G>A p.V775I | Missense Mutation (SNP) | VAF 27/354 reads (8%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.04); catalogued as rs781893058, COSV50564437; called by muse, mutect2
- PCDHB5 | c.1477C>A p.Q493K | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.152); catalogued as COSV50647325; called by muse, mutect2, varscan2
- PCDHGA8 | c.1060A>G p.S354G | Missense Mutation (SNP) | VAF 19/253 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.033); catalogued as rs759255236, COSV53898741; called by muse, mutect2
- PCDHGC3 | c.797T>C p.V266A | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV52743175; called by muse, mutect2
- PCM1 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1286077979, COSV61514597; called by muse, mutect2, varscan2
- PDCD11 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 19/201 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as COSV63933013; called by muse, mutect2, varscan2
- PDPR | c.920A>G p.K307R | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.463); catalogued as rs768909579, COSV55349110; called by muse, mutect2, varscan2
- PDZD2 | c.7138G>T p.G2380W | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV104390560, COSV56850751; called by muse, mutect2, varscan2
- PDZD4 | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1290487093, COSV51245346; called by muse, mutect2, varscan2
- PEAK1 | c.4054C>T p.P1352S | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV56930748; called by muse, mutect2, varscan2
- PHF6 | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 14/144 reads (10%) | catalogued as CM1311557, COSV59699218; called by muse, mutect2, varscan2
- PHKA1 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59801766; called by muse, mutect2
- PHLDB1 | c.638G>A p.G213D | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV61876388; called by muse, mutect2, varscan2
- PHLPP2 | c.2576T>C p.V859A | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as COSV62422532; called by muse, mutect2, varscan2
- PIGB | c.1399del p.S467Vfs*12 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | catalogued as rs35751662; called by mutect2, pindel, varscan2
- PIK3CG | c.2583T>A p.D861E | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63245499; called by muse, mutect2, varscan2
- PJVK | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.951); catalogued as COSV57867725, COSV57869813; called by muse, mutect2
- PKLR | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as COSV61360364; called by muse, mutect2
- PLA2G12B | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 35/269 reads (13%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.999); catalogued as rs762983146, COSV65978197; called by muse, mutect2, varscan2
- PLCB4 | c.1136T>C p.M379T | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV53793185; called by muse, mutect2, varscan2
- PLCE1 | c.6576G>T p.E2192D | Missense Mutation (SNP) | VAF 52/448 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53336780; called by muse, mutect2, varscan2
- PLCG1 | c.1885T>G p.F629V | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54815231; called by muse, mutect2, varscan2
- PLD1 | c.2326T>C p.Y776H | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60565338; called by muse, mutect2
- PLEKHA5 | c.2995del p.T999Lfs*17 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | catalogued as rs759995048, COSV54701412; called by mutect2, varscan2
- PLEKHG4B | c.1147G>A p.A383T (on ENST00000283426; = p.A739T on NM_052909.5) | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs558371500, COSV52043468; called by muse, mutect2, varscan2
- PLXNA2 | c.698T>C p.L233P | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65437638; called by muse, mutect2
- PLXNB1 | c.4675C>A p.L1559M | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.124); catalogued as COSV56486595; called by muse, mutect2, varscan2
- PNLDC1 | c.1458C>A p.Y486* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as COSV99277143; called by muse, mutect2
- POLD1 | c.2489A>G p.E830G | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54529566; called by muse, mutect2
- POLQ | c.1108+2T>C p.X370_splice | Splice Site (SNP) | VAF 34/317 reads (11%) | catalogued as COSV51745800; called by muse, mutect2
- POLR1A | c.2371C>A p.L791I | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as COSV55689135; called by muse, mutect2
- POMT1 | c.1526A>G p.N509S | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV61225048; called by muse, mutect2
- POP1 | c.2254del p.T752Lfs*12 | Frame Shift Del (DEL) | VAF 22/212 reads (10%) | catalogued as rs868622083, COSV62893071; called by mutect2, pindel
- PPFIA2 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61020557; called by muse, varscan2
- PPFIA3 | c.2285G>A p.S762N | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV61949432; called by muse, mutect2, varscan2
- PPL | c.932G>A p.C311Y | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV62044571; called by muse, mutect2, varscan2
- PPP1R15A | c.752del p.R251Hfs*89 | Frame Shift Del (DEL) | VAF 17/88 reads (19%) | catalogued as rs989468095, COSV99566352; called by mutect2, pindel, varscan2
- PPP2R3A | c.2257G>A p.A753T | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.168); catalogued as COSV53859593; called by muse, mutect2, varscan2
- PPP4R3A | c.1531C>T p.L511F (on ENST00000554943 / NM_001366432.1; = p.L498F on NM_001284280.1) | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1219458748, COSV61503499; called by muse, mutect2, varscan2
- PPWD1 | c.1672T>C p.W558R | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51549639; called by muse, mutect2, varscan2
- PRAM1 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs760422876, COSV55311797; called by muse, mutect2, varscan2
- PRDM11 | c.380del p.P127Rfs*40 (on ENST00000530656 / NM_001359633.1; = p.P93Rfs*40 on NM_001256695.1) | Frame Shift Del (DEL) | VAF 10/87 reads (11%) | catalogued as COSV55440445; called by mutect2, pindel, varscan2
- PRICKLE2 | c.1001C>T p.A334V (on ENST00000295902; = p.A278V on NM_198859.4) | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55762811; called by muse, mutect2
- PRKCE | c.1805C>T p.A602V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.641); catalogued as COSV60312568; called by muse, mutect2, varscan2
- PRKCQ | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 22/224 reads (10%) | catalogued as COSV54106179; called by muse, mutect2, varscan2
- PRORP | c.1413del p.F471Lfs*30 | Frame Shift Del (DEL) | VAF 26/249 reads (10%) | catalogued as rs766680749; called by mutect2, pindel, varscan2
- PRPF40B | c.1937T>C p.L646P (on ENST00000380281; = p.L633P on NM_012272.3) | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV53297884; called by muse, mutect2, varscan2
- PRRC1 | c.433C>G p.H145D | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56987648; called by muse, mutect2
- PRRC2A | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.988); catalogued as COSV63224306; called by muse, mutect2, varscan2
- PRSS54 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.06); catalogued as rs1365082743, COSV54688934; called by mutect2, varscan2
- PSMD2 | c.1925C>T p.A642V | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV59528934; called by muse, mutect2
- PSTK | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1054354010, COSV64397197; called by muse, mutect2
- PTCD1 | c.403A>T p.T135S | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as COSV52856422; called by muse, mutect2, varscan2
- PTCH1 | c.1541A>G p.D514G | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV59462980; called by muse, mutect2, varscan2
- PTGFRN | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.036); catalogued as rs150341125, COSV67797729; called by muse, mutect2, varscan2
- PTK2 | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61782471; called by muse, mutect2
- PTPRD | c.2924C>T p.A975V | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.149); catalogued as COSV61928632; called by muse, mutect2, varscan2
- PTPRD | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 30/368 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV61928643; called by muse, mutect2
- PTPRG | c.2975G>A p.R992H | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773599761, COSV55628767; called by muse, mutect2, varscan2
- PTPRJ | c.1901T>C p.V634A | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.141); catalogued as COSV69249785; called by muse, mutect2, varscan2
- PTPRN2 | c.191T>C p.V64A | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV67022465; called by muse, mutect2, varscan2
- PTPRZ1 | c.4946T>G p.F1649C | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV66430314; called by muse, mutect2, varscan2
- PUM2 | c.349-1G>T p.X117_splice | Splice Site (SNP) | VAF 12/94 reads (13%) | catalogued as COSV57577780; called by muse, mutect2
- PXDN | c.1217A>G p.D406G | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53227006; called by muse, mutect2, varscan2
- R3HDM2 | c.2204T>C p.M735T | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV61284698; called by muse, mutect2, varscan2
- RAB33A | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57061141; called by muse, mutect2, varscan2
- RAB6B | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99557778; called by muse, mutect2
- RABGAP1L | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as rs377226119; called by muse, mutect2, varscan2
- RABL6 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374394708; called by mutect2, varscan2
- RALBP1 | c.601A>G p.T201A | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as COSV50034288; called by muse, mutect2, varscan2
- RB1 | c.2346A>G p.I782M | Missense Mutation (SNP) | VAF 45/374 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57296263, COSV57316174; called by muse, mutect2, varscan2
- RBM18 | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 22/255 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV69873985; called by muse, mutect2
- RC3H1 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV51197868; called by muse, mutect2, varscan2
- RC3H2 | c.68A>C p.E23A | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs779484116, COSV59010312; called by muse, mutect2, varscan2
- RCBTB2 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs560160674, COSV60649087; called by muse, mutect2, varscan2
- RDX | c.1412del p.P471Lfs*35 | Frame Shift Del (DEL) | VAF 28/252 reads (11%) | catalogued as COSV100563010; called by mutect2, pindel, varscan2
- REL | c.535+1G>A p.X179_splice | Splice Site (SNP) | VAF 10/187 reads (5%) | catalogued as COSV54362359, COSV54366495; called by muse, mutect2
- RERE | c.3905G>A p.R1302Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs779763814, COSV61937178; called by muse, mutect2
- REV3L | c.5494G>A p.V1832M | Missense Mutation (SNP) | VAF 28/296 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs768017978, COSV62614969; called by muse, mutect2
- RGS22 | c.1064A>T p.D355V | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV62657292; called by muse, mutect2
- RGS22 | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV62657308; called by muse, mutect2
- RIMKLB | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs746816555, COSV100223959, COSV55235390; called by muse, mutect2, varscan2
- RING1 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 13/359 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV63002275; called by muse, mutect2
- RNF148 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs376463521; called by muse, mutect2
- RNF150 | c.1081A>C p.T361P | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV60786756; called by muse, mutect2
- RNF185 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs201108552; called by muse, mutect2, varscan2
- RNF220 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs575154952, COSV62404734; called by muse, mutect2, varscan2
- RNF34 | c.927C>A p.S309= | Splice Region (SNP) | VAF 17/122 reads (14%) | catalogued as COSV63441965, COSV63443351; called by muse, mutect2
- ROBO2 | c.3233del p.P1078Qfs*95 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | catalogued as rs745519558, COSV100168583; called by mutect2, varscan2
- RP1L1 | c.3260G>A p.R1087K | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1315279562, COSV66751699; called by muse, mutect2
- RPL31 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as rs148930940; called by muse, mutect2, varscan2
- RRP9 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773847916, COSV51752926, COSV99232619; called by muse, mutect2, varscan2
- RSAD1 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1430440273, COSV51956913; called by muse, mutect2, varscan2
- RSBN1 | c.1471T>C p.F491L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV54731058; called by muse, mutect2, varscan2
- RSL1D1 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 58/418 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV63077401; called by muse, mutect2, varscan2
- RSU1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.868); catalogued as rs771114539, COSV61708940; called by muse, mutect2
- RTN1 | c.286A>G p.T96A | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV50718771; called by muse, mutect2
- RUNX1T1 | c.212T>C p.F71S (on ENST00000265814 / NM_001198628.1; = p.F44S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.756); catalogued as COSV104380168, COSV56137571; called by muse, mutect2
- RUSC1 | c.2545G>A p.V849M (on ENST00000368352 / NM_001105203.2; = p.V380M on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772797925, COSV52738133; called by muse, varscan2
- RUVBL1 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59474894; called by muse, mutect2
- RYR2 | c.9620A>G p.N3207S | Missense Mutation (SNP) | VAF 31/319 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as COSV63662117; called by muse, mutect2, varscan2
- SACS | c.4235T>C p.L1412P | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.591); catalogued as COSV66534191; called by muse, mutect2, varscan2
- SALL1 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.815); catalogued as rs59416382, COSV51753288; called by muse, mutect2, varscan2
- SAMD8 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs773937515, COSV65509104; called by muse, mutect2, varscan2
- SAMD9L | c.2957G>A p.R986H | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs769611275, COSV59079412; called by muse, mutect2, varscan2
- SATB1 | c.552G>A p.W184* | Nonsense Mutation (SNP) | VAF 19/162 reads (12%) | catalogued as COSV58667494; called by muse, mutect2, varscan2
- SCAF4 | c.2582G>A p.R861H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1273742454, COSV99531995; called by muse, mutect2, varscan2
- SCAF4 | c.749del p.P250Hfs*96 | Frame Shift Del (DEL) | VAF 16/112 reads (14%) | catalogued as COSV54589079; called by mutect2, pindel, varscan2
- SCARA3 | c.1186C>A p.L396I | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57269277; called by muse, mutect2
- SCN3B | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV54798131; called by muse, mutect2, varscan2
- SCN4A | c.4913G>A p.S1638N | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV101438558, COSV71125596; called by muse, mutect2, varscan2
- SEC24D | c.1876G>A p.V626M | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763670327, COSV54876758; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 37/98 reads (38%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMA3D | c.2128C>T p.R710W | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs1265790609, COSV52387550; called by muse, mutect2
- SEMA3F | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV50028248; called by muse, mutect2, varscan2
- SEMA7A | c.818A>G p.E273G | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.47); catalogued as COSV56089257; called by muse, mutect2, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 20/98 reads (20%) | catalogued as rs750651342; called by mutect2, varscan2
- SEPTIN1 | c.586C>T p.R196W (on ENST00000321367; = p.R149W on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs765085320, COSV58441354; called by muse, mutect2, varscan2
- SETD6 | c.818A>G p.Q273R (on ENST00000219315 / NM_001160305.4; = p.Q249R on NM_024860.3) | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as COSV50746412; called by muse, mutect2
- SEZ6L | c.1474C>T p.H492Y | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50658041; called by muse, mutect2, varscan2
- SF3B1 | c.296A>G p.E99G | Missense Mutation (SNP) | VAF 44/343 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV59206554; called by muse, mutect2, varscan2
- SF3B2 | c.777+2T>C p.X259_splice | Splice Site (SNP) | VAF 14/158 reads (9%) | catalogued as COSV59426935; called by muse, mutect2
- SF3B4 | c.93A>T p.E31D | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54963919; called by muse, mutect2
- SFI1 | c.2531C>G p.A844G (on ENST00000400288 / NM_001007467.3; = p.A813G on NM_014775.4) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63475277; called by muse, mutect2, varscan2
- SGCA | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.187); catalogued as rs760608643, COSV56248299; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SGO1 | c.973del p.M325Cfs*28 | Frame Shift Del (DEL) | VAF 12/88 reads (14%) | catalogued as rs747473028; called by mutect2, varscan2
- SGO2 | c.1943del p.F648Sfs*14 | Frame Shift Del (DEL) | VAF 42/199 reads (21%) | catalogued as rs771387868; called by mutect2, varscan2
- SH3BGRL2 | c.164dup p.E56Gfs*16 | Frame Shift Ins (INS) | VAF 20/156 reads (13%) | catalogued as rs1200713575; called by mutect2, pindel, varscan2
- SH3RF2 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as rs370760801, COSV63037079; called by muse, mutect2, varscan2
- SH3RF2 | c.1237T>C p.C413R | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100767599; called by muse, mutect2
- SHC3 | c.1574C>A p.T525N | Missense Mutation (SNP) | VAF 40/295 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV65436802; called by muse, mutect2, varscan2
- SHROOM2 | c.4397C>T p.T1466I | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV66604577; called by muse, mutect2, varscan2
- SIPA1L3 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs747791015, COSV55908874; called by muse, mutect2, varscan2
- SKA3 | c.630G>T p.M210I | Missense Mutation (SNP) | VAF 41/487 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs147994613; called by muse, mutect2
- SLC12A2 | c.1787T>C p.V596A | Missense Mutation (SNP) | VAF 23/328 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV52468185; called by muse, mutect2
- SLC12A4 | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57925363; called by muse, mutect2, varscan2
- SLC15A4 | c.1088C>T p.T363M | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs142880588; called by muse, mutect2, varscan2
- SLC17A3 | c.644C>A p.S215Y | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57759443; called by muse, mutect2, varscan2
- SLC25A13 | c.1248G>T p.R416S | Missense Mutation (SNP) | VAF 16/271 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55703755; called by muse, mutect2
- SLC25A2 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53403057; called by muse, mutect2
- SLC26A5 | c.941A>G p.N314S | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs1348672403, COSV59698105; called by muse, mutect2
- SLC26A6 | c.1535A>G p.H512R | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV56570016; called by muse, mutect2
- SLC34A2 | c.1340G>A p.G447D | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as rs1259023473, COSV65940649; called by muse, mutect2, varscan2
- SLC35F4 | c.394T>A p.S132T (on ENST00000339762 / NM_001352015.2; = p.S96T on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV60262755; called by muse, mutect2
- SLC35G5 | c.833A>G p.H278R | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55310426, COSV55312824; called by muse, mutect2
- SLC47A1 | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as rs773686189, COSV54498951, COSV54502625; called by muse, mutect2
- SLC52A1 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); catalogued as rs778417188, COSV54692335; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC5A4 | c.101T>C p.I34T | Missense Mutation (SNP) | VAF 34/350 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV56668349; called by muse, mutect2
- SLC7A7 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 38/324 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763715975, COSV53536331; called by muse, mutect2, varscan2
- SLC8A1 | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.475); catalogued as COSV60470916; called by muse, mutect2, varscan2
- SLC9A5 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1489255321, COSV55360183; called by muse, mutect2
- SLC9C2 | c.1051C>A p.L351I | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as COSV62943800; called by muse, mutect2
- SLCO4A1 | c.1468G>A p.G490R | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs577773991, COSV53889236; called by muse, mutect2
- SLCO5A1 | c.2269T>G p.W757G | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52653681; called by muse, mutect2
- SLCO6A1 | c.1625del p.K542Rfs*13 | Frame Shift Del (DEL) | VAF 9/61 reads (15%) | catalogued as rs866444182; called by mutect2, pindel, varscan2
- SLFN11 | c.2118G>T p.Q706H | Missense Mutation (SNP) | VAF 24/269 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57697527; called by muse, mutect2
- SLITRK5 | c.2102G>A p.S701N | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV61520972; called by muse, mutect2, varscan2
- SLX4 | c.5192C>T p.A1731V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs778690592, COSV53560864; called by muse, mutect2, varscan2
- SLX4 | c.1406del p.P469Hfs*4 | Frame Shift Del (DEL) | VAF 17/159 reads (11%) | catalogued as rs774532876; called by mutect2, pindel, varscan2
- SMC4 | c.643A>G p.S215G | Missense Mutation (SNP) | VAF 11/224 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as COSV58445345; called by muse, mutect2
- SMG1 | c.6545G>A p.R2182H | Missense Mutation (SNP) | VAF 44/436 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.308); catalogued as rs565896040, COSV67169504; called by muse, varscan2
- SNAP91 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52115155; called by muse, mutect2, varscan2
- SNIP1 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as rs746942786, COSV56165589; called by muse, mutect2
- SNX2 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761196086, COSV65347676; called by muse, mutect2, varscan2
- SORBS1 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.559); catalogued as rs369258399; called by muse, mutect2, varscan2
- SOX5 | c.1070T>G p.L357R | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.04); catalogued as COSV58618382; called by muse, mutect2, varscan2
- SP100 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs1435330745, COSV50974532; called by muse, mutect2, varscan2
- SPAG1 | c.2751A>G p.I917M | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV52557888; called by muse, mutect2, varscan2
- SPAG5 | c.1904T>C p.V635A | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV58800005; called by muse, mutect2
- SPATA16 | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 28/474 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.029); catalogued as COSV63526558; called by muse, mutect2
- SPEG | c.6942del p.R2315Gfs*38 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as rs1452292712; called by mutect2, pindel, varscan2
- SPG7 | c.1993G>A p.G665R (on ENST00000268704; = p.G672R on NM_003119.4) | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369503365, CM085725; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPHKAP | c.3434A>G p.E1145G | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV60868628; called by muse, mutect2, varscan2
- SPIRE2 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142759329; called by muse, mutect2, varscan2
- SPOCK1 | c.187-1G>T p.X63_splice | Splice Site (SNP) | VAF 19/263 reads (7%) | catalogued as COSV56436859; called by muse, mutect2
- SPTAN1 | c.6484G>A p.V2162I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as rs371095095; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTBN5 | c.7052G>A p.G2351D | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as COSV58016375; called by muse, mutect2
- SPTBN5 | c.4406G>A p.R1469Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375198417; called by mutect2, varscan2
- SRSF6 | c.1009A>G p.R337G | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV54826986; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.660G>A p.M220I | Missense Mutation (SNP) | VAF 9/88 reads (10%) | PolyPhen possibly damaging (0.885); catalogued as COSV52534936; called by muse, mutect2, varscan2
- ST8SIA1 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs1197616067, COSV53950547, COSV53955326; called by muse, mutect2, varscan2
- STAB1 | c.6364G>A p.D2122N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs199702251, COSV100194529; called by mutect2, varscan2
- STAG3 | c.3046del p.S1016Pfs*16 | Frame Shift Del (DEL) | VAF 36/372 reads (10%) | catalogued as rs950641068; called by mutect2, pindel
- STIP1 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54176856; called by muse, mutect2, varscan2
- STON2 | c.2689A>G p.T897A (on ENST00000649389 / NM_001366849.2; = p.T840A on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.279); catalogued as COSV50842312; called by muse, mutect2, varscan2
- STOX1 | c.2032G>A p.V678M | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.06); catalogued as rs201271155; called by muse, mutect2
- STX1B | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52679624; called by muse, mutect2, varscan2
- SULF1 | c.1689A>C p.E563D | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.028); catalogued as COSV52673317; called by muse, mutect2, varscan2
- SUPT3H | c.680T>A p.V227D (on ENST00000371460 / NM_181356.3; = p.V216D on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.135); catalogued as COSV60933957; called by muse, mutect2
- SUPT5H | c.433T>C p.Y145H | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV63238451; called by muse, mutect2
- SUPV3L1 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62844598; called by muse, mutect2, varscan2
- SURF2 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV64332110; called by muse, mutect2, varscan2
- SYBU | c.836G>T p.R279I (on ENST00000276646 / NM_001099754.2; = p.R278I on NM_017786.6) | Missense Mutation (SNP) | VAF 28/338 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52614300; called by muse, mutect2
- SYNCRIP | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 54/476 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV62286614; called by muse, mutect2, varscan2
- TACC2 | c.2347del p.Q783Rfs*32 | Frame Shift Del (DEL) | VAF 14/149 reads (9%) | catalogued as rs750901207; called by mutect2, pindel
- TACR3 | c.33A>G p.I11M | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV59197986; called by muse, mutect2, varscan2
- TAF1 | c.3610C>T p.R1204W (on ENST00000373790 / NM_138923.4; = p.R1225W on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52107508; called by muse, mutect2, varscan2
- TAF10 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as rs1396669422, COSV54989602; called by muse, mutect2, varscan2
- TAF2 | c.3584C>A p.P1195H | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV65416533; called by muse, mutect2
- TAF5L | c.1289A>G p.D430G | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as COSV51077365; called by muse, mutect2, varscan2
- TAF6 | c.900+1G>A p.X300_splice | Splice Site (SNP) | VAF 10/91 reads (11%) | catalogued as rs1027255449, COSV59840595; called by muse, mutect2, varscan2
- TAGAP | c.986G>C p.S329T | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.078); catalogued as rs781342205, COSV57850526; called by muse, mutect2, varscan2
- TANGO6 | c.965T>C p.V322A | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV55760300; called by muse, mutect2
- TAOK2 | c.2719G>A p.E907K | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV54233010; called by muse, mutect2, varscan2
- TAS1R3 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs577691125, COSV59562196; called by muse, mutect2, varscan2
- TAS2R4 | c.280A>T p.S94C | Missense Mutation (SNP) | VAF 36/350 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV56093183; called by muse, mutect2, varscan2
- TBC1D5 | c.255G>T p.R85S | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV53749354; called by muse, mutect2, varscan2
- TBC1D8B | c.1087A>G p.I363V | Missense Mutation (SNP) | VAF 48/423 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV52175910; called by muse, mutect2, varscan2
- TBL3 | c.1163G>T p.G388V | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60340631; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 26/160 reads (16%) | catalogued as rs758822980; called by mutect2, varscan2
- TEAD2 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.102); catalogued as rs1438708434, COSV55561514; called by muse, mutect2, varscan2
- TECPR2 | c.3029G>T p.G1010V | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63969007, COSV63971902; called by muse, mutect2, varscan2
- TECTA | c.2399del p.F800Sfs*24 | Frame Shift Del (DEL) | VAF 24/218 reads (11%) | catalogued as rs1468171008; called by mutect2, pindel, varscan2
- TEK | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs764269402, COSV66227441; called by muse, mutect2, varscan2
- TEKT1 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); catalogued as rs561916829, COSV58622112; called by muse, mutect2
- TENM1 | c.474A>C p.E158D | Missense Mutation (SNP) | VAF 64/313 reads (20%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV64425137; called by muse, mutect2, varscan2
- TENM3 | c.2147G>T p.C716F | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69299400, COSV69301974; called by muse, varscan2
547 further variants in this file (271 protein-altering or splice-affecting, 264 silent, 12 other) are not listed here.
